Gene-level copy-number profile of tumor specimen TCGA-OR-A5L2-01A from TCGA case TCGA-OR-A5L2, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 83.6 years (30,535 days).
Specimen TCGA-OR-A5L2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.49d3c8a0-667e-4599-b8eb-1cd0e3449062.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5L2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d6256c86-d081-4550-8705-28f016133be6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 671; copy number 2: 3,792; copy number 3: 13,645; copy number 4: 15,070; copy number 5: 15,688; copy number 6: 7,616; copy number 7: 1,047; copy number 8: 990; copy number 9: 208; copy number 10: 36; copy number 11: 256; copy number 12: 79; copy number 13: 318; copy number 14: 65; copy number 15: 5; copy number 17: 9; copy number 22: 19; copy number 25: 5; copy number 26: 52; copy number 27: 8; copy number 29: 72; copy number 33: 13; copy number 41: 22; copy number 51: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5L2-01A-11D-A309-01): tumor purity 0.3, ploidy 4.78, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,789,179–26,118,408, 95 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,176 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:73,805,754–74,136,892, 5 genes, copy number 11 (within-gene range 7–11): LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2.
- chr3:75,906,695–77,649,964, 1 gene, copy number 10 (within-gene range 6–10): ROBO2.
- chr3:76,434,018–82,808,021, 37 genes, copy number 10–13: CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr4:17,427,696–37,869,978, 168 genes, copy number 11–22 (broad region; genes not listed).
- chr4:41,359,607–48,494,389, 88 genes, copy number 9 (broad region; genes not listed).
- chr4:169,094,259–169,612,627, 5 genes, copy number 10: SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1.
- chr7:71,779,491–72,447,151, 1 gene, copy number 12 (within-gene range 8–12): CALN1.
- chr7:72,103,181–74,254,458, 68 genes, copy number 9–12 (broad region; genes not listed).
- chr9:1,977,784–6,066,714, 77 genes, copy number 15–29 (broad region; genes not listed).
- chr9:19,705,338–19,705,655, 1 gene, copy number 10: C11orf98P1.
- chr9:27,948,078–30,575,012, 12 genes, copy number 27–33 (within-gene range 4–33): LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242.
- chr9:31,644,576–33,182,865, 27 genes, copy number 25–51 (within-gene range 4–51): HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1.
- chr9:35,360,540–37,120,446, 73 genes, copy number 26–41 (broad region; genes not listed).
- chr9:37,160,137–37,160,237, 1 gene, copy number 41: Y_RNA.
- chr11:65,711,996–76,804,555, 447 genes, copy number 9–17 (broad region; genes not listed).
- chr12:43,835,967–44,503,596, 6 genes, copy number 11 (within-gene range 7–11): TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2.
- chr16:63,314,264–64,738,564, 13 genes, copy number 9 (within-gene range 7–9): AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1.
- chr20:8,831,186–9,481,242, 5 genes, copy number 10 (within-gene range 8–10): RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4.
- chr20:40,685,848–44,434,596, 69 genes, copy number 9–12 (broad region; genes not listed).
- chr22:15,290,718–16,956,808, 72 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 669. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
